MMRF case MMRF_1716 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4a5a1396-9e77-4c47-a15b-61b863ef950d

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 84 years; Vital status: Dead; Days to death: 77 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 84.1 years (30,731 days); ISS stage: II; Days to last known disease status: 77 days; Days to last follow up: 77 days.
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 76 days.

Follow-up (2 entries)
- Days to follow up: -368 days (-1.0 years); ECOG performance status: 4.
- Follow-up contact recording only the day: day 77.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Lactate Dehydrogenase 3.72 µkat/L.
- Hemoglobin 5.46 mmol/L.
- Platelets 147 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Lambda 8.29 mg/dL.
- Absolute Neutrophil 5.8 ×10⁹/L.
- Immunoglobulin G 65.4 g/L.
- Calcium 2.85 mmol/L.
- Leukocytes 10.3 ×10⁹/L.
- C-Reactive Protein 2.72 mg/dL.
- Immunoglobulin A 0.559 g/L.
- M Protein 6.54 g/dL.
- Serum Free Immunoglobulin Light Chain, Kappa 133 mg/dL.
- Creatinine 137 µmol/L.
- Beta 2 Microglobulin 4.98 µg/mL.
- Immunoglobulin M 0.231 g/L.
- Total Protein 9.49 g/dL.
- Glucose 6.66 mmol/L.
- Blood Urea Nitrogen 16 mmol/L.
- Albumin 21 g/L.

Other clinical attributes
- Day -368: Weight: 69 kg; Height: 158 cm.

Biospecimens (2 samples)
- Sample MMRF_1716_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -368 days (-1.0 years).
- Sample MMRF_1716_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -368 days (-1.0 years).
